Somatic mutation profile of tumor specimen TCGA-Q1-A73O-01A (aliquot TCGA-Q1-A73O-01A-11D-A32I-09) from TCGA case TCGA-Q1-A73O, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: GX; Age at diagnosis: 37.2 years (13,601 days).
Specimen TCGA-Q1-A73O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e1ef453e-5ca2-4022-b968-6f5dfe7c1175.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-Q1-A73O-10B (Blood Derived Normal), aliquot TCGA-Q1-A73O-10B-01D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fc47b753-2394-4e58-b6fa-6fc609e57c76

The open-access MAF lists 1,593 somatic variants for this specimen: 1,141 protein-altering or splice-affecting, 418 silent, 34 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,005, Silent 418, Nonsense Mutation 97, Splice Site 26, Intron 15, 5'Flank 6, RNA 5, 3'Flank 4, Splice Region 4, 3'UTR 4, Translation Start Site 3, Nonstop Mutation 3.

Variants (750 of 1,593; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AR | c.1823G>A p.R608Q | Missense Mutation (SNP) | VAF 45/130 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs137852573, CM920073, COSV65954700; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CPLANE1 | c.*2776C>T | 3'UTR (SNP) | VAF 11/70 reads (16%) | catalogued as rs749421099, COSV57056397; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1973G>A p.R658Q (on ENST00000281708 / NM_001349798.2; = p.R578Q on NM_018315.5) | Missense Mutation (SNP) | VAF 27/66 reads (41%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as rs759610249, COSV55905466; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- SDHAF2 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 31/109 reads (28%) | hotspot (GDC flag); SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV57098949, COSV57100559; called by muse, mutect2, varscan2
- A2M | c.2549C>T p.A850V | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV100588484, COSV100588570; called by muse, mutect2
- AACS | c.752C>G p.S251* | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as rs1009972110, COSV55535639; called by muse, mutect2, varscan2
- AAK1 | c.1366C>G p.Q456E | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV65907313; called by muse, mutect2, varscan2
- ABCA5 | c.4536-1G>C p.X1512_splice | Splice Site (SNP) | VAF 29/123 reads (24%) | catalogued as COSV67016267; called by muse, mutect2, varscan2
- ABCB1 | c.3598G>C p.D1200H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55948290; called by muse, mutect2, varscan2
- ABCB11 | c.1870G>A p.D624N | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV55588035, COSV55588705; called by muse, mutect2, varscan2
- ABCC10 | c.3238C>T p.H1080Y (on ENST00000372530 / NM_001198934.2; = p.H1052Y on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV55086060; called by muse, mutect2, varscan2
- ABCC4 | c.3478G>T p.E1160* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as COSV65311106; called by muse, mutect2, varscan2
- ABCD3 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.267); catalogued as rs1023581453, COSV59865693; called by muse, mutect2, varscan2
- ABCF3 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.091); catalogued as rs766166794, COSV53047589, COSV99490900; called by muse, varscan2
- ABTB2 | c.813C>G p.I271M | Missense Mutation (SNP) | VAF 23/81 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV54386228; called by muse, mutect2, varscan2
- AC126283.2 | c.1342C>T p.R448C | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.34); catalogued as rs754851037, COSV67097939; called by muse, mutect2, varscan2
- ACIN1 | c.623C>T p.S208L | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.942); catalogued as COSV52974807; called by muse, mutect2, varscan2
- ACOX2 | c.2045G>C p.*682Sext*29 | Nonstop Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV57148158, COSV57150444; called by muse, mutect2, varscan2
- ACSL4 | c.2014C>G p.R672G (on ENST00000340800 / NM_022977.2; = p.R631G on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as COSV61613889; called by muse, mutect2, varscan2
- ACSM4 | c.1198G>C p.D400H | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV68067400; called by muse, mutect2, varscan2
- ACSS1 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs778094981, COSV60219003; called by mutect2, varscan2
- ACTB | c.1043C>G p.S348W | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV59317066, COSV59317805; called by muse, mutect2, varscan2
- ACTBL2 | c.484C>G p.H162D | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.977); catalogued as COSV70661112, COSV70661677; called by muse, mutect2, varscan2
- ACTN3 | c.1313C>G p.S438W | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV100074134; called by muse, mutect2, varscan2
- ACTR8 | c.481C>T p.H161Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.44); PolyPhen benign (0.342); catalogued as COSV51635795, COSV51637198; called by muse, mutect2, varscan2
- ADA2 | c.832G>A p.E278K (on ENST00000262607; = p.E37K on NM_177405.3) | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1224892373, COSV52830923; called by muse, varscan2
- ADAM15 | c.1783A>T p.I595F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as COSV55125968; called by muse, mutect2
- ADAMTS5 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.7); PolyPhen benign (0.129); catalogued as COSV53177595; called by muse, mutect2, varscan2
- ADCY4 | c.1511C>G p.S504C | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV60253161; called by muse, mutect2, varscan2
- ADCY9 | c.2214G>C p.M738I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV53573624; called by muse, mutect2, varscan2
- ADGRF1 | c.572G>C p.R191T | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.134); catalogued as COSV51944555, COSV51946042; called by muse, mutect2, varscan2
- ADGRG2 | c.2067G>C p.K689N (on ENST00000379869 / NM_001079858.3; = p.K686N on NM_005756.4) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV61338320; called by muse, mutect2, varscan2
- ADGRL2 | c.1441C>T p.Q481* | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as COSV54660981; called by muse, mutect2, varscan2
- ADGRV1 | c.6635G>A p.G2212E | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67982301; called by muse, mutect2, varscan2
- ADGRV1 | c.14800G>A p.E4934K | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.366); catalogued as COSV67982313; called by muse, mutect2, varscan2
- AFF1 | c.2899C>T p.H967Y | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.88); PolyPhen benign (0.01); catalogued as COSV100321020, COSV57118454; called by muse, mutect2, varscan2
- AGMAT | c.704G>A p.R235K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV65435765; called by muse, mutect2, varscan2
- AGO3 | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV55792378; called by muse, mutect2, varscan2
- AGO3 | c.1391G>C p.R464T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55792387; called by muse, varscan2
- AHNAK | c.15352C>T p.Q5118* | Nonsense Mutation (SNP) | VAF 6/30 reads (20%) | catalogued as COSV57209094, COSV57224718; called by muse, mutect2
- AIFM1 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54853684; called by muse, mutect2, varscan2
- AKAP11 | c.3904G>A p.E1302K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs751509415, COSV50294819; called by muse, mutect2, varscan2
- AKAP13 | c.5989G>A p.E1997K (on ENST00000394518 / NM_007200.5; = p.E2001K on NM_006738.6) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV63452784; called by muse, mutect2, varscan2
- AKAP8L | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.54); catalogued as COSV68473121; called by muse, mutect2, varscan2
- AKIP1 | c.260G>C p.R87T | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.836); catalogued as COSV55148739; called by muse, mutect2, varscan2
- AKT3 | c.164C>T p.S55L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.16); catalogued as COSV55612517; called by muse, mutect2, varscan2
- ALDH18A1 | c.1783G>C p.D595H | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.035); catalogued as COSV64662353; called by muse, mutect2, varscan2
- ALDH1L2 | c.1978G>C p.E660Q | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV51554544; called by muse, mutect2, varscan2
- ALDH3B2 | c.520G>C p.E174Q | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.898); catalogued as COSV100823984; called by muse, mutect2, varscan2
- ALMS1 | c.11923G>A p.E3975K | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52506840; called by muse, mutect2, varscan2
- ALOX5 | c.1571C>G p.S524* | Nonsense Mutation (SNP) | VAF 27/77 reads (35%) | catalogued as COSV65551815; called by muse, mutect2, varscan2
- ALPK2 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs113027270, COSV64491728; called by muse, mutect2, varscan2
- AMACR | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); catalogued as COSV59460359; called by muse, mutect2, varscan2
- AMACR | c.413G>A p.R138K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.073); catalogued as rs1000843834, COSV59460367; called by muse, mutect2, varscan2
- AMELX | c.381C>G p.Y127* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | catalogued as COSV61625941; called by muse, mutect2, varscan2
- AMER1 | c.2500C>A p.L834I | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.71); PolyPhen benign (0.339); catalogued as COSV57657791; called by muse, mutect2, varscan2
- AMER3 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); catalogued as COSV58465919; called by muse, mutect2, varscan2
- AMOT | c.1521C>G p.F507L (on ENST00000371959 / NM_001113490.1; = p.F98L on NM_133265.3) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as COSV59062088; called by muse, mutect2, varscan2
- ANAPC5 | c.1765G>C p.E589Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.056); catalogued as COSV99945973; called by muse, mutect2, varscan2
- ANAPC5 | c.1553G>C p.R518T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as COSV55842078; called by muse, mutect2, varscan2
- ANO8 | c.914G>C p.R305T | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.708); catalogued as COSV50174717; called by muse, mutect2, varscan2
- ANXA11 | c.954C>G p.F318L | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as COSV55415565; called by muse, mutect2, varscan2
- AOC2 | c.1599C>G p.N533K | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53825474; called by muse, mutect2, varscan2
- AP2A1 | c.831G>C p.K277N | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV62817814; called by muse, mutect2, varscan2
- AP3D1 | c.2356C>G p.L786V | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.115); catalogued as COSV61426144; called by muse, mutect2, varscan2
- AP4B1 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV56724187; called by muse, mutect2, varscan2
- APC | c.730-1G>A p.X244_splice | Splice Site (SNP) | VAF 18/73 reads (25%) | catalogued as CS941417, COSV57335072; called by muse, mutect2, varscan2
- APLNR | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV57241937; called by muse, mutect2, varscan2
- APOB | c.9635G>C p.R3212T | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as COSV51924762, COSV51930251; called by muse, mutect2, varscan2
- APOBEC3G | c.638G>C p.R213T | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.072); catalogued as COSV101349072, COSV68470170; called by muse, mutect2, varscan2
- APOD | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.23); catalogued as rs5954; called by muse, mutect2, varscan2
- AQR | c.4408G>A p.E1470K | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV50031287; called by muse, mutect2, varscan2
- ARFGEF2 | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.017); catalogued as COSV100904043; called by muse, mutect2, varscan2
- ARGLU1 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.117); catalogued as COSV62271433; called by muse, mutect2, varscan2
- ARHGAP10 | c.54C>G p.F18L | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV60597054; called by muse, mutect2, varscan2
- ARHGAP17 | c.2096G>A p.R699Q (on ENST00000289968 / NM_001006634.3; = p.R621Q on NM_018054.6) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.968); catalogued as rs752563170, COSV51505867; called by muse, mutect2, varscan2
- ARHGAP5 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV61534713; called by muse, mutect2, varscan2
- ARHGEF2 | c.2897G>C p.R966T (on ENST00000361247 / NM_001162383.2; = p.R938T on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV58108477; called by muse, mutect2, varscan2
- ARHGEF28 | c.1475C>G p.S492C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV55252348; called by muse, mutect2, varscan2
- ARID1A | c.3551C>T p.S1184L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV61374636; called by muse, mutect2, varscan2
- ARID3A | c.1473G>C p.M491I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as COSV55043869; called by muse, mutect2, varscan2
- ARID4A | c.2905G>A p.E969K | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV62162911; called by muse, mutect2, varscan2
- ARPC2 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.134); catalogued as COSV55284138; called by muse, mutect2, varscan2
- ASCC3 | c.13C>G p.R5G | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV61227394, COSV61232687; called by muse, mutect2, varscan2
- ASGR2 | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV54689747; called by mutect2, varscan2
- ASIC3 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.043); catalogued as rs745324943, COSV52521259; called by muse, mutect2, varscan2
- ASMT | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as rs1233714732, COSV67109736; called by muse, mutect2, varscan2
- ASPM | c.7694G>A p.R2565K | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.972); catalogued as COSV54127618; called by mutect2, varscan2
- ASTN1 | c.3487C>G p.L1163V | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62494524, COSV62496511; called by muse, mutect2, varscan2
- ATAD2 | c.1022G>A p.R341K | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.277); catalogued as COSV54879252; called by muse, mutect2, varscan2
- ATG3 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV51926455; called by muse, mutect2, varscan2
- ATG5 | c.397G>A p.D133N | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV58347232; called by muse, mutect2, varscan2
- ATM | c.1789C>G p.P597A | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.492); catalogued as rs1555072070, COSV53735669; ClinVar: uncertain significance; called by muse, mutect2
- ATN1 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.84); catalogued as COSV63110630; called by muse, mutect2, varscan2
- ATP2A1 | c.1833C>G p.I611M | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.812); catalogued as COSV62868925; called by muse, mutect2, varscan2
- ATP7B | c.607G>T p.D203Y | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV54436964; called by muse, mutect2, varscan2
- ATRIP | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57176562; called by muse, mutect2, varscan2
- AZIN1 | c.589C>T p.H197Y | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV61479642; called by muse, mutect2, varscan2
- B3GALNT2 | c.148C>G p.H50D | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.108); catalogued as COSV58356099; called by muse, mutect2, varscan2
- B9D1 | c.565G>C p.D189H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV52069317; called by muse, mutect2, varscan2
- BAG5 | c.858G>C p.M286I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.136); catalogued as COSV54570679, COSV54570780; called by muse, mutect2, varscan2
- BAHCC1 | c.7424C>T p.S2475L | Missense Mutation (SNP) | VAF 22/44 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV100311221; called by muse, mutect2, varscan2
- BAZ2B | c.2192C>G p.S731C | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs771370768, COSV58595087; called by muse, mutect2, varscan2
- BCLAF1 | c.484C>G p.Q162E | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as COSV62141325, COSV62145613; called by muse, mutect2, varscan2
- BDP1 | c.6713G>T p.G2238V | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100702780; called by muse, varscan2
- BEST1 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57120288; called by muse, mutect2, varscan2
- BLID | c.308C>T p.S103F | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV73340201; called by muse, varscan2
- BPIFC | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55911620; called by muse, mutect2, varscan2
- BPTF | c.5068G>A p.E1690K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as COSV58834654; called by muse, mutect2, varscan2
- BRD4 | c.3673G>A p.E1225K | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.97); catalogued as rs745807590, COSV54584336; called by mutect2, varscan2
- BRD8 | c.96G>T p.M32I | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV50146296; called by muse, mutect2, varscan2
- BRDT | c.2447C>T p.S816L | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.781); catalogued as COSV62864186; called by muse, mutect2, varscan2
- BRICD5 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT tolerated (0.63); PolyPhen benign (0.171); catalogued as rs1355209279, COSV57027304; called by muse, mutect2, varscan2
- BRINP3 | c.981G>A p.M327I | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV66518655; called by muse, mutect2, varscan2
- BRIP1 | c.2191G>C p.E731Q | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.92); catalogued as COSV51994491, COSV51997018; called by muse, mutect2, varscan2
- BSN | c.2476C>A p.L826I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.059); catalogued as COSV56515390, COSV99608664; called by muse, mutect2, varscan2
- BSPRY | c.202-1G>A p.X68_splice | Splice Site (SNP) | VAF 12/78 reads (15%) | catalogued as COSV65242467; called by muse, mutect2
- BST1 | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.995); catalogued as rs375412643; called by muse, mutect2, varscan2
- BTBD7 | c.921G>C p.L307F | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV54134840; called by muse, mutect2, varscan2
- BTBD9 | c.982C>G p.Q328E | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.085); catalogued as COSV58423079; called by muse, mutect2, varscan2
- BTN3A1 | c.974G>C p.R325T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV50024612; called by muse, mutect2, varscan2
- BUB1 | c.1416G>A p.M472I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57061284, COSV57062328; called by muse, mutect2, varscan2
- C11orf65 | c.552G>A p.M184I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV67597165; called by muse, mutect2, varscan2
- C1QL1 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 11/45 reads (24%) | catalogued as COSV53646823; called by muse, mutect2, varscan2
- C1QTNF9 | c.227G>A p.R76Q | Missense Mutation (SNP) | VAF 39/197 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs779386798, COSV59656776; called by muse, mutect2, varscan2
- C20orf194 | c.571G>C p.E191Q | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52693933; called by muse, mutect2, varscan2
- C2CD3 | c.452C>T p.S151L | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58091661; called by mutect2, varscan2
- C2CD3 | c.11G>A p.R4Q | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); catalogued as COSV100076190, COSV58091671; called by muse, mutect2, varscan2
- C2orf50 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs141429224, COSV67510550; called by muse, mutect2, varscan2
- C2orf78 | c.2746G>C p.E916Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV68517087; called by muse, mutect2, varscan2
- C3orf20 | c.1119C>G p.F373L | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV53784069; called by muse, mutect2, varscan2
- C4orf19 | c.687G>C p.L229F | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); catalogued as rs768318711, COSV52649083; called by muse, mutect2, varscan2
- C5orf46 | c.110C>A p.S37* | Nonsense Mutation (SNP) | VAF 12/47 reads (26%) | catalogued as COSV59153751; called by muse, mutect2, varscan2
- C6orf136 | c.543G>C p.E181D (on ENST00000376473 / NM_001109938.3; = p.E47D on NM_145029.4) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.289); catalogued as COSV53313216; called by muse, mutect2, varscan2
- CACHD1 | c.1000C>T p.Q334* | Nonsense Mutation (SNP) | VAF 16/44 reads (36%) | catalogued as COSV51551263; called by muse, mutect2, varscan2
- CACHD1 | c.2399C>T p.S800F | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV99261575; called by muse, mutect2, varscan2
- CACNA1F | c.5296C>T p.P1766S | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as rs782658023, COSV59903785; called by muse, mutect2, varscan2
- CALML6 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.006); catalogued as COSV57069025; called by muse, mutect2, varscan2
- CALR | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV57121673; called by muse, mutect2, varscan2
- CAMK1 | c.501G>C p.K167N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56538248; called by muse, mutect2, varscan2
- CAMK2A | c.910C>G p.L304V | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.175); catalogued as COSV62245814; called by muse, mutect2, varscan2
- CAPN1 | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as COSV54197638; called by muse, mutect2, varscan2
- CAPRIN1 | c.418G>C p.E140Q | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58219128; called by muse, mutect2, varscan2
- CAPRIN1 | c.2054G>A p.G685E | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV58219142; called by muse, mutect2, varscan2
- CARD10 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV52655356; called by muse, mutect2, varscan2
- CARMIL1 | c.2398C>T p.R800* | Nonsense Mutation (SNP) | VAF 16/62 reads (26%) | catalogued as rs1185105289, COSV61515828; called by muse, mutect2, varscan2
- CASK | c.2128G>C p.D710H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV59364248; called by muse, mutect2, varscan2
- CASP1 | c.889G>C p.D297H (on ENST00000436863 / NM_033292.4; = p.D276H on NM_001223.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100782844, COSV62056194; called by muse, mutect2, varscan2
- CBLB | c.855C>G p.F285L | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51424082, COSV51426076; called by muse, mutect2, varscan2
- CBLC | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs763654909, COSV54321856, COSV54321980; called by muse, mutect2, varscan2
- CC2D2A | c.3820C>G p.Q1274E | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as COSV67502949, COSV67503599; called by muse, mutect2, varscan2
- CCDC125 | c.1469C>G p.S490C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.35); catalogued as COSV67287869; called by muse, mutect2, varscan2
- CCDC125 | c.1137G>C p.Q379H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV67287871; called by muse, mutect2, varscan2
- CCDC144A | c.1743G>C p.K581N | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.168); catalogued as COSV60697424; called by muse, mutect2, varscan2
- CCDC159 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV52259241, COSV99264697; called by muse, mutect2, varscan2
- CCDC17 | c.1690G>T p.E564* | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV59646637; called by muse, mutect2, varscan2
- CCDC171 | c.3133G>A p.A1045T | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs145385823; called by muse, mutect2, varscan2
- CCDC180 | c.4828G>A p.D1610N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV63828829; called by muse, mutect2, varscan2
- CCDC66 | c.2471G>C p.R824T (on ENST00000394672 / NM_001353147.1; = p.R790T on NM_001012506.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.178); catalogued as COSV58302738; called by muse, mutect2, varscan2
- CCDC91 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV60340791; called by muse, mutect2, varscan2
- CCL15 | c.176C>T p.S59L | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.131); catalogued as rs991873200; called by muse, mutect2, varscan2
- CCT5 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54723466; called by muse, varscan2
- CDCA2 | c.14C>G p.S5* | Nonsense Mutation (SNP) | VAF 14/70 reads (20%) | catalogued as COSV55339642; called by muse, mutect2, varscan2
- CDCA5 | c.467C>G p.S156C | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV51869029; called by muse, mutect2, varscan2
- CDCA5 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.081); catalogued as COSV51869037; called by muse, mutect2, varscan2
- CDHR2 | c.321G>C p.Q107H | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.258); catalogued as rs6886860; called by muse, mutect2, varscan2
- CDK10 | c.468G>C p.R156S (on ENST00000353379 / NM_052988.5; = p.R85S on NM_052987.4) | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV57046376; called by muse, mutect2, varscan2
- CDK16 | c.56G>A p.R19Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); catalogued as rs187232602, COSV99331469; called by muse, mutect2, varscan2
- CDK5RAP3 | c.799-1G>A p.X267_splice | Splice Site (SNP) | VAF 16/78 reads (21%) | catalogued as COSV58114610; called by muse, mutect2, varscan2
- CDKAL1 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.01); catalogued as rs1187563078, COSV51181710; called by muse, mutect2, varscan2
- CDKN2B | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.218); catalogued as COSV52805148; called by muse, mutect2, varscan2
- CDON | c.1199-1G>C p.X400_splice | Splice Site (SNP) | VAF 7/24 reads (29%) | catalogued as COSV54996546; called by muse, mutect2, varscan2
- CDT1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as rs1444682337, COSV99967084; called by muse, mutect2
- CECR2 | c.2971G>C p.E991Q (on ENST00000342247 / NM_001290047.2; = p.E807Q on NM_001290046.1) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV52838896; called by muse, mutect2, varscan2
- CELA3A | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV51582633; called by muse, mutect2, varscan2
- CELSR1 | c.8827G>A p.E2943K | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.363); catalogued as rs1555902888, COSV53086755; called by mutect2, varscan2
- CELSR3 | c.8359C>G p.L2787V | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); catalogued as rs142990854; called by muse, mutect2, varscan2
- CEP112 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.306); catalogued as rs1212309742, COSV67137948, COSV67145441; called by muse, mutect2, varscan2
- CEP128 | c.1122C>G p.F374L | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.67); PolyPhen benign (0.034); catalogued as COSV53677575, COSV99382899; called by muse, mutect2, varscan2
- CEP135 | c.1976C>T p.S659L | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as rs747930985, COSV57259032; called by muse, mutect2, varscan2
- CEP152 | c.1225C>G p.Q409E | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.05); catalogued as COSV100358391, COSV57858176; called by muse, mutect2, varscan2
- CEP152 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | catalogued as COSV57858189; called by muse, mutect2, varscan2
- CEP55 | c.226C>G p.Q76E | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV65184827; called by muse, mutect2, varscan2
- CFAP58 | c.1299G>C p.K433N | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV57211708, COSV57211715; called by muse, mutect2, varscan2
- CFP | c.316G>C p.G106R | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55949990; called by muse, mutect2, varscan2
- CHD4 | c.145C>G p.P49A | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.12); catalogued as rs779921079, COSV58897670; called by mutect2, varscan2
- CHD9 | c.6845C>G p.S2282* | Nonsense Mutation (SNP) | VAF 16/73 reads (22%) | catalogued as COSV54607664, COSV54609086; called by muse, mutect2, varscan2
- CHRD | c.1678G>A p.D560N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1447741434, COSV52606739; called by muse, mutect2
- CHRD | c.2847G>C p.E949D | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.046); catalogued as COSV52606761, COSV52610570, COSV99200799; called by muse, mutect2, varscan2
- CHRFAM7A | c.251G>A p.G84E | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.14); catalogued as rs769830262, COSV55397146, COSV55397874; called by muse, mutect2, varscan2
- CHRM4 | c.878C>G p.S293C | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); catalogued as COSV63126213; called by muse, mutect2, varscan2
- CIAO2A | c.356C>G p.S119C | Missense Mutation (SNP) | VAF 19/54 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as COSV55538143; called by muse, mutect2, varscan2
- CIC | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.011); catalogued as COSV50554919; called by muse, mutect2, varscan2
- CILP | c.962G>A p.R321K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV56022990; called by muse, mutect2, varscan2
- CIT | c.966G>C p.L322F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.977); catalogued as COSV55864745; called by muse, mutect2, varscan2
- CKAP2 | c.936G>C p.K312N (on ENST00000378037 / NM_001098525.2; = p.K311N on NM_018204.5) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.711); catalogued as COSV51621510, COSV99318371; called by muse, mutect2, varscan2
- CKAP5 | c.2038C>T p.Q680* | Nonsense Mutation (SNP) | VAF 19/81 reads (23%) | catalogued as COSV56365906; called by muse, mutect2, varscan2
- CKB | c.1034C>G p.S345* | Nonsense Mutation (SNP) | VAF 11/74 reads (15%) | catalogued as COSV62379436; called by muse, mutect2, varscan2
- CKMT2 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54172624; called by muse, mutect2, varscan2
- CLBA1 | c.104G>C p.S35T | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as COSV66347937; called by muse, varscan2
- CLCNKA | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 21/75 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs764634668, COSV58891060; called by muse, mutect2, varscan2
- CLDN2 | c.153G>C p.W51C | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61020710; called by muse, mutect2, varscan2
- CLIP1 | c.3812C>G p.S1271* (on ENST00000620786 / NM_001247997.1; = p.S1260* on NM_002956.2) | Nonsense Mutation (SNP) | VAF 8/38 reads (21%) | catalogued as COSV56799829; called by muse, mutect2, varscan2
- CLK2 | c.215G>A p.R72Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1435869687, COSV62876827; called by muse, mutect2, varscan2
- CLSTN2 | c.2168G>C p.R723P | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.388); catalogued as COSV71719714; called by muse, mutect2, varscan2
- CLUH | c.100G>A p.E34K (on ENST00000435359; = p.E72K on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV70928325; called by muse, mutect2, varscan2
- CLVS2 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.268); catalogued as COSV51559258, COSV51560504, COSV99252977; called by muse, mutect2, varscan2
- CMTR1 | c.314G>A p.G105E | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65089950; called by muse, mutect2, varscan2
- CMYA5 | c.3179C>T p.S1060L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.129); catalogued as COSV71405000; called by muse, mutect2, varscan2
- CNBD2 | c.1252G>C p.E418Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.083); catalogued as COSV62586674; called by muse, mutect2, varscan2
- CNGA3 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV55623420; called by muse, mutect2, varscan2
- CNOT3 | c.222G>C p.K74N | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99651550; called by muse, mutect2, varscan2
- CNOT3 | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV55361810; called by muse, mutect2, varscan2
- CNOT6L | c.830G>C p.R277T (on ENST00000504123 / NM_001286790.2; = p.R272T on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as COSV53698437; called by muse, mutect2, varscan2
- CNTN6 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1479830103, COSV63167544; called by mutect2, varscan2
- CNTNAP1 | c.3677G>A p.R1226Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs1481806507, COSV52849055; called by muse, mutect2, varscan2
- CNTNAP2 | c.999C>G p.F333L | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as COSV62162875, COSV62168443; called by muse, mutect2, varscan2
- COL11A1 | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 52/214 reads (24%) | catalogued as rs377107722, CM1411315, COSV100615377, COSV62181543; called by muse, varscan2
- COL11A1 | c.1643C>T p.S548L | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.067); catalogued as COSV62178371, COSV62180680; called by muse, varscan2
- COL12A1 | c.4282C>G p.Q1428E | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT tolerated (0.56); PolyPhen benign (0.006); catalogued as COSV100485487; called by muse, mutect2, varscan2
- COL25A1 | c.715C>G p.L239V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV67648428; called by muse, mutect2, varscan2
- COL4A3 | c.1561C>G p.L521V | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.372); catalogued as COSV67414507; called by muse, mutect2, varscan2
- COL4A3 | c.4420C>G p.L1474V | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CD941651, COSV67414516; called by muse, mutect2, varscan2
- COL6A3 | c.3112G>C p.E1038Q | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.224); catalogued as COSV55084844; called by muse, mutect2, varscan2
- COPA | c.3175G>A p.E1059K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54100588; called by muse, mutect2, varscan2
- COPG1 | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs535955599, COSV59113303; called by muse, mutect2, varscan2
- COQ7 | c.647G>C p.R216T | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV58981476; called by muse, mutect2, varscan2
- CPA3 | c.283G>T p.D95Y | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56043518, COSV56044469; called by muse, mutect2, varscan2
- CPLANE2 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs774923410, COSV65056740; called by muse, mutect2, varscan2
- CPSF3 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as COSV53008890; called by muse, mutect2, varscan2
- CPSF6 | c.1484G>C p.R495T | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV57013535; called by muse, mutect2, varscan2
- CPSF7 | c.1000G>A p.E334K (on ENST00000394888 / NM_001136040.4; = p.E377K on NM_024811.4) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.908); catalogued as rs977204304, COSV61210675; called by muse, mutect2, varscan2
- CREBRF | c.880G>C p.E294Q | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.87); catalogued as COSV51632327; called by muse, mutect2, varscan2
- CREBRF | c.1108G>A p.D370N | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV51632341; called by muse, mutect2, varscan2
- CRISPLD1 | c.1484G>C p.R495T | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV51546208; called by muse, mutect2, varscan2
- CRLF1 | c.1216G>T p.E406* | Nonsense Mutation (SNP) | VAF 19/72 reads (26%) | catalogued as rs781453921, COSV62260590; called by muse, mutect2, varscan2
- CRTC1 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV100119161, COSV58717708; called by muse, mutect2, varscan2
- CRTC1 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58717725; called by muse, mutect2, varscan2
- CRX | c.763G>A p.G255S | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as COSV55757696; called by muse, mutect2, varscan2
- CSAG1 | c.122G>A p.R41Q | Missense Mutation (SNP) | VAF 44/172 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.975); catalogued as rs182694662, COSV63400084; called by muse, mutect2, varscan2
- CSMD1 | c.10579G>A p.E3527K (on ENST00000520002; = p.E3526K on NM_033225.6) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59287663, COSV59312285; called by muse, mutect2, varscan2
- CSTF3 | c.1580G>C p.R527T | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60610328; called by muse, mutect2, varscan2
- CTNND1 | c.1108G>C p.E370Q | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV62382761; called by muse, mutect2, varscan2
- CUL4A | c.2112G>A p.M704I (on ENST00000375440 / NM_001008895.4; = p.M604I on NM_003589.3) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58372099; called by muse, mutect2, varscan2
- CUX1 | c.531-1G>A p.X177_splice (on ENST00000292535 / NM_181552.4; = p.X188_splice on NM_001913.5) | Splice Site (SNP) | VAF 8/48 reads (17%) | catalogued as COSV52895315; called by muse, mutect2, varscan2
- CWF19L2 | c.1840C>G p.Q614E | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV56510742; called by muse, mutect2, varscan2
- CYLC2 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.132); catalogued as COSV66336924; called by muse, mutect2, varscan2
- CYP11A1 | c.1411G>C p.E471Q | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as COSV51431177, COSV51431358; called by muse, mutect2, varscan2
- CYP2J2 | c.671C>T p.S224L | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as COSV64605844; called by muse, mutect2, varscan2
- CYP2R1 | c.908C>T p.S303L | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV58127091; called by muse, mutect2, varscan2
- CYRIA | c.436-1G>C p.X146_splice | Splice Site (SNP) | VAF 18/49 reads (37%) | catalogued as COSV62864601; called by muse, mutect2, varscan2
- DAPK3 | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV56662615; called by muse, mutect2
- DARS2 | c.967G>A p.E323K | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV53406326; called by muse, mutect2, varscan2
- DBT | c.268G>C p.D90H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1369264656, COSV64495165; called by muse, mutect2, varscan2
- DCDC1 | c.2178C>G p.I726M | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as COSV60838662; called by muse, mutect2, varscan2
- DCHS1 | c.9806C>G p.S3269* | Nonsense Mutation (SNP) | VAF 9/29 reads (31%) | catalogued as COSV54996773; called by muse, mutect2, varscan2
- DCP1B | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as COSV54968219; called by muse, mutect2, varscan2
- DDX23 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.038); catalogued as COSV57282627; called by muse, varscan2
- DDX3X | c.1189G>C p.D397H (on ENST00000399959; = p.D398H on NM_001356.5) | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.823); catalogued as COSV67863328; called by muse, mutect2, varscan2
- DDX43 | c.1806G>C p.L602F | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64812482; called by muse, varscan2
- DEGS1 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60378897; called by muse, mutect2, varscan2
- DENND2C | c.1368G>C p.K456N (on ENST00000393274 / NM_001256404.2; = p.K399N on NM_198459.4) | Missense Mutation (SNP) | VAF 24/92 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); catalogued as COSV67920886; called by muse, mutect2, varscan2
- DENND3 | c.481G>A p.G161R | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99370423; called by muse, mutect2, varscan2
- DGKK | c.2385G>C p.K795N | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.469); catalogued as COSV101053118, COSV101053178, COSV65706969; called by muse, mutect2, varscan2
- DHDDS | c.478C>G p.H160D | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99360310; called by muse, mutect2, varscan2
- DHX30 | c.1018G>A p.E340K (on ENST00000445061 / NM_138615.3; = p.E301K on NM_014966.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.056); catalogued as COSV53136530; called by muse, mutect2, varscan2
- DIRAS3 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV63970595; called by muse, mutect2, varscan2
- DIS3L | c.703G>C p.E235Q (on ENST00000319212 / NM_001143688.3; = p.E152Q on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.353); catalogued as COSV59911674; called by muse, mutect2, varscan2
- DLEC1 | c.860G>C p.R287T | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV57297720; called by muse, mutect2, varscan2
- DMBT1 | c.6197G>C p.G2066A (on ENST00000338354 / NM_001377530.1; = p.G1309A on NM_004406.3) | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100354835, COSV57539354, COSV57540192; called by muse, mutect2, varscan2
- DMC1 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53258720; called by muse, mutect2, varscan2
- DMWD | c.1002G>C p.W334C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52176841; called by muse, mutect2, varscan2
- DNAH10 | c.8782G>A p.E2928K (on ENST00000409039; = p.E2867K on NM_207437.3) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1224791719, COSV68990918, COSV68995687; called by muse, mutect2, varscan2
- DNAH5 | c.9395C>T p.S3132F | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.608); catalogued as COSV54215442; called by muse, mutect2, varscan2
- DNAH5 | c.568C>T p.Q190* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | catalogued as COSV54215455; called by muse, mutect2, varscan2
- DNAH7 | c.11064+1G>C p.X3688_splice | Splice Site (SNP) | VAF 9/45 reads (20%) | catalogued as COSV56758264; called by muse, mutect2, varscan2
- DNAH8 | c.7237C>T p.Q2413* | Nonsense Mutation (SNP) | VAF 17/80 reads (21%) | catalogued as rs1367544031, COSV59435680; called by muse, mutect2, varscan2
- DNAJC6 | c.1367C>G p.S456* | Nonsense Mutation (SNP) | VAF 16/43 reads (37%) | catalogued as COSV54772635; called by muse, mutect2, varscan2
- DNMBP | c.3727C>G p.P1243A | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.077); catalogued as COSV60623132; called by muse, mutect2, varscan2
- DNMT3A | c.1180G>A p.D394N | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.483); catalogued as COSV53045913; called by muse, mutect2, varscan2
- DOCK11 | c.6040G>C p.E2014Q | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV52236247; called by muse, mutect2, varscan2
- DOCK6 | c.4526C>G p.S1509C | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV53912954; called by muse, mutect2, varscan2
- DOCK7 | c.3485C>A p.S1162Y (on ENST00000635253 / NM_001367561.1; = p.S1131Y on NM_033407.3) | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV52000969; called by muse, mutect2, varscan2
- DOP1A | c.3412C>G p.Q1138E | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.003); catalogued as COSV52708619; called by muse, mutect2, varscan2
- DPY19L3 | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV60475551; called by muse, mutect2, varscan2
- DSG4 | c.2289G>A p.M763I | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV57389955; called by muse, mutect2, varscan2
- DSP | c.3826C>G p.Q1276E | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.9); catalogued as rs1487309339, COSV101131631, COSV65792140; called by muse, mutect2, varscan2
- DST | c.9640G>C p.E3214Q | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV55006369, COSV99757994; called by muse, mutect2
- DUSP6 | c.442G>C p.E148Q | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.661); catalogued as COSV99683971; called by muse, mutect2, varscan2
- EBF3 | c.1409G>A p.R470Q (on ENST00000355311 / NM_001375392.1; = p.R461Q on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.285); catalogued as rs772614493, COSV62472903; called by muse, mutect2, varscan2
- EEA1 | c.949G>A p.D317N | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs773417932, COSV59284040; called by muse, mutect2, varscan2
- EHHADH | c.556C>T p.Q186* | Nonsense Mutation (SNP) | VAF 10/58 reads (17%) | catalogued as COSV51628977; called by muse, mutect2, varscan2
- EIF2AK1 | c.1469G>C p.R490T | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as rs748149087, COSV52237859; called by muse, mutect2, varscan2
- EIF3D | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV53403149; called by muse, mutect2, varscan2
- EIF4A2 | c.160G>C p.E54Q | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV60623514; called by muse, mutect2, varscan2
- EIF4A2 | c.425G>C p.R142P | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.827); catalogued as COSV56216376; called by muse, mutect2
- EIF4G1 | c.3713C>G p.S1238C (on ENST00000346169 / NM_198241.3; = p.S1043C on NM_004953.5) | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV59990037; called by muse, mutect2, varscan2
- EIF5A | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV59748360; called by muse, mutect2, varscan2
- ELAVL1 | c.803G>C p.G268A | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV60966114, COSV60966287; called by muse, mutect2, varscan2
- ELF3 | c.198C>G p.F66L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV62837883; called by muse, mutect2, varscan2
- EMC10 | c.551C>T p.S184L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as rs369893864; called by muse, mutect2, varscan2
- EPAS1 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV55385439; called by muse, mutect2, varscan2
- EPHA2 | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV64452607; called by muse, mutect2, varscan2
- EPHA4 | c.2725G>A p.E909K | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.543); catalogued as COSV56044865; called by muse, mutect2
- EPHB2 | c.2518G>A p.E840K (on ENST00000400191 / NM_001309193.2; = p.E841K on NM_004442.7) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV101006841, COSV65861343; called by muse, mutect2, varscan2
- EPRS1 | c.290C>T p.S97F | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV65098168; called by muse, mutect2, varscan2
- EPX | c.1337G>C p.R446T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.02); catalogued as COSV56595709; called by muse, mutect2, varscan2
- ERAP1 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 19/87 reads (22%) | catalogued as rs751798914, COSV57086628; called by muse, mutect2, varscan2
- ERBB3 | c.1256G>C p.G419A | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as COSV57248809, COSV57255244; called by muse, mutect2, varscan2
- ERCC6 | c.3080C>G p.S1027* | Nonsense Mutation (SNP) | VAF 25/67 reads (37%) | catalogued as COSV63388902; called by muse, mutect2, varscan2
- ERMARD | c.1165C>G p.Q389E | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs1269585236, COSV64647878; called by muse, mutect2, varscan2
- ETS2 | c.127C>G p.L43V | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.251); catalogued as COSV62872649; called by muse, mutect2, varscan2
- ETV1 | c.782G>A p.R261K | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.876); catalogued as COSV54139828; called by muse, mutect2, varscan2
- EXD2 | c.1650-1G>C p.X550_splice (on ENST00000312994 / NM_001193362.1; = p.X425_splice on NM_018199.3) | Splice Site (SNP) | VAF 5/24 reads (21%) | catalogued as COSV57278971; called by muse, mutect2
- EXOC3 | c.1789G>A p.E597K | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.32); PolyPhen benign (0.104); catalogued as COSV59266206; called by muse, mutect2, varscan2
- EXOC6 | c.2304G>C p.K768N | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV53322043; called by muse, mutect2, varscan2
- EXOC6B | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); catalogued as COSV55550164; called by muse, mutect2, varscan2
- EZR | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61453206; called by muse, mutect2, varscan2
- FAAP100 | c.2124C>G p.I708M | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV59884642; called by muse, mutect2, varscan2
- FABP3 | c.280C>T p.H94Y | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.389); catalogued as rs1348660115, COSV60001779; called by muse, mutect2, varscan2
- FAH | c.68C>G p.S23W | Missense Mutation (SNP) | VAF 34/102 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55720801; called by muse, mutect2, varscan2
- FAM120B | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777800651, COSV53002675; called by muse, mutect2, varscan2
- FAM13B | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.82); catalogued as COSV50365294; called by muse, mutect2, varscan2
- FAM160B1 | c.903G>C p.Q301H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.343); catalogued as COSV65087698; called by muse, mutect2, varscan2
- FAM161B | c.1358G>C p.R453T (on ENST00000651776; = p.R390T on NM_152445.3) | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV54101728, COSV54102841; called by muse, mutect2, varscan2
- FAM168B | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 17/69 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.052); catalogued as COSV66303831; called by muse, mutect2, varscan2
- FAM177A1 | c.368C>G p.S123C (on ENST00000382406 / NM_001289022.2; = p.S146C on NM_173607.5) | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55240267, COSV55240556; called by muse, mutect2, varscan2
- FAM199X | c.1153G>C p.D385H | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV55433423; called by muse, mutect2, varscan2
- FAM20A | c.422G>C p.R141T | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.026); catalogued as COSV56836250; called by muse, mutect2, varscan2
- FAM214A | c.709G>C p.E237Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV55923186; called by muse, mutect2, varscan2
- FAM71B | c.1333C>G p.H445D | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV57228302, COSV57229745; called by muse, mutect2, varscan2
- FAM9C | c.149G>A p.R50K | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.364); catalogued as COSV61775404; called by muse, mutect2, varscan2
- FARP1 | c.1936G>A p.E646K | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as rs765401742, COSV60333860; called by muse, mutect2, varscan2
- FASN | c.4558G>C p.E1520Q | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.005); catalogued as COSV60752298; called by muse, mutect2, varscan2
- FAT2 | c.4154C>G p.S1385* | Nonsense Mutation (SNP) | VAF 23/64 reads (36%) | catalogued as COSV55816706, COSV55831000; called by muse, mutect2, varscan2
- FAT2 | c.3497C>G p.S1166C | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.806); catalogued as COSV55816715; called by muse, mutect2, varscan2
- FBN1 | c.3338-1G>A p.X1113_splice | Splice Site (SNP) | VAF 9/37 reads (24%) | catalogued as CS161885, COSV57313187; called by muse, mutect2, varscan2
- FBN3 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.833); catalogued as rs775897428, COSV54457140; called by muse, mutect2, varscan2
- FBXO21 | c.1733C>T p.S578L (on ENST00000330622 / NM_033624.3; = p.S571L on NM_015002.3) | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.171); catalogued as COSV57972225; called by muse, mutect2, varscan2
- FBXO9 | c.902G>A p.R301K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV55055312; called by muse, mutect2, varscan2
- FBXW4 | c.825G>C p.Q275H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.113); catalogued as COSV58707323; called by muse, mutect2, varscan2
- FBXW7 | c.829C>G p.Q277E (on ENST00000281708 / NM_001349798.2; = p.Q197E on NM_018315.5) | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV55905493, COSV55917375; called by muse, mutect2, varscan2
- FDPS | c.1180C>G p.L394V | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV52738896; called by muse, mutect2, varscan2
- FER | c.2207G>C p.R736T | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as COSV55287392, COSV55294364; called by muse, mutect2, varscan2
- FEZF2 | c.244G>C p.E82Q | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV51862383, COSV51862865; called by muse, mutect2, varscan2
- FGFR2 | c.2375C>T p.S792L | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as COSV100335362, COSV100335449; called by muse, mutect2, varscan2
- FGG | c.527G>A p.G176E | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60194939; called by muse, mutect2, varscan2
- FGR | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV64969394; called by muse, mutect2, varscan2
- FLG | c.190G>C p.D64H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773267945, COSV64238164; called by muse, mutect2, varscan2
- FLNB | c.3505G>A p.E1169K | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.626); catalogued as COSV55874909; called by muse, mutect2, varscan2
- FLT1 | c.1483G>A p.D495N | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV56723783; called by muse, mutect2, varscan2
- FMN2 | c.1257C>G p.I419M | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.691); catalogued as COSV60425357; called by muse, mutect2, varscan2
- FNBP4 | c.1400C>G p.S467C | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55447475; called by muse, mutect2, varscan2
- FOXD2 | c.450G>C p.L150F | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58303435; called by muse, mutect2, varscan2
- FOXP1 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.599); catalogued as COSV59538416, COSV59553898; called by muse, mutect2, varscan2
- FOXP4 | c.1537-1G>A p.X513_splice (on ENST00000307972 / NM_001012426.1; = p.X500_splice on NM_138457.3) | Splice Site (SNP) | VAF 16/36 reads (44%) | catalogued as COSV57219117; called by muse, mutect2, varscan2
- FOXR2 | c.208G>C p.D70H | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59258111; called by muse, mutect2, varscan2
- FRMPD1 | c.3854C>T p.S1285F | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.467); catalogued as COSV66699781; called by muse, mutect2, varscan2
- FRMPD1 | c.3979C>G p.P1327A | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1237176375, COSV66699784; called by muse, mutect2, varscan2
- FRS2 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV54724513, COSV54730275; called by muse, mutect2, varscan2
- FUBP3 | c.146C>T p.S49L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.319); catalogued as COSV100156218, COSV60512985; called by muse, mutect2, varscan2
- FUNDC2 | c.387A>C p.K129N | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.869); catalogued as COSV65670491, COSV65671332; called by muse, mutect2, varscan2
- FUT8 | c.1033G>C p.E345Q (on ENST00000360689 / NM_001371534.1; = p.E182Q on NM_004480.4) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.307); catalogued as COSV61282406, COSV61286786; called by muse, mutect2, varscan2
- FYB2 | c.2044G>A p.D682N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV58583843; called by muse, mutect2, varscan2
- FZD5 | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54943244; called by muse, mutect2, varscan2
- G6PC3 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as COSV52242225; called by muse, mutect2, varscan2
- GABRG1 | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54964229, COSV99777501; called by muse, mutect2, varscan2
- GABRQ | c.625G>A p.E209K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV64781451; called by muse, mutect2, varscan2
- GANC | c.1846G>C p.D616H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | PolyPhen probably damaging (1); catalogued as COSV58808050; called by muse, mutect2, varscan2
- GAPDHS | c.1064C>G p.S355C | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55880237; called by muse, mutect2, varscan2
- GAPVD1 | c.4124C>T p.P1375L (on ENST00000394104; = p.P1384L on NM_015635.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.394); catalogued as COSV52921870; called by muse, mutect2, varscan2
- GBP1 | c.1641G>C p.E547D | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as COSV65083123; called by muse, mutect2, varscan2
- GBP1 | c.574G>A p.D192N | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as COSV99054199; called by muse, mutect2, varscan2
- GDF9 | c.223G>A p.G75R | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.564); catalogued as COSV51526043, COSV51527039; called by muse, mutect2, varscan2
- GGA3 | c.1112C>G p.S371C (on ENST00000537686 / NM_138619.4; = p.S338C on NM_014001.5) | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.72); catalogued as rs750932108, COSV55455994; called by muse, mutect2, varscan2
- GHDC | c.1258G>C p.D420H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56987323; called by muse, mutect2, varscan2
- GIMAP1 | c.319C>A p.L107I | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100212271, COSV56187671; called by muse, mutect2, varscan2
- GIMAP2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.08); catalogued as COSV56234815; called by muse, mutect2, varscan2
- GIPC3 | c.207C>G p.F69L | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.089); catalogued as COSV59258642; called by muse, mutect2
- GIT2 | c.2137G>A p.E713K (on ENST00000355312 / NM_057169.5; = p.E635K on NM_014776.5) | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58079671; called by muse, mutect2, varscan2
- GLIS2 | c.734C>T p.S245F | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52109924; called by muse, mutect2, varscan2
- GLIS3 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV60926876; called by muse, varscan2
- GLT1D1 | c.131G>C p.R44P | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765354223, COSV55878595, COSV55880001; called by muse, mutect2, varscan2
- GNA12 | c.240C>G p.I80M | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51739852; called by muse, mutect2, varscan2
- GNAQ | c.955G>A p.D319N | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as rs1352440197, COSV54108983; called by muse, mutect2, varscan2
- GNL2 | c.1106C>G p.S369C | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as COSV100895033, COSV66079981; called by muse, mutect2, varscan2
- GNPTAB | c.256G>A p.D86N | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54778552; called by muse, mutect2, varscan2
- GOLGA3 | c.1204G>C p.E402Q | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.862); catalogued as COSV52628332; called by muse, mutect2
- GOLGA4 | c.3079G>C p.E1027Q | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs781529814, COSV62710055; called by muse, mutect2, varscan2
- GOLGB1 | c.1983G>C p.L661F | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.277); catalogued as COSV61463718; called by muse, mutect2, varscan2
- GOLGB1 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV61463730; called by muse, mutect2, varscan2
- GPANK1 | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.94); PolyPhen benign (0.018); catalogued as COSV63263691; called by muse, mutect2, varscan2
- GPAT3 | c.197C>G p.S66C | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV52356239; called by muse, mutect2, varscan2
- GPATCH8 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs866653249, COSV59193947; called by muse, mutect2, varscan2
- GPC1 | c.1321G>A p.E441K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1206538075, COSV50863014; called by muse, mutect2
- GPRIN3 | c.817G>C p.E273Q | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.56); PolyPhen benign (0.01); catalogued as COSV60884535; called by muse, mutect2
- GRAMD4 | c.624C>T p.L208= | Splice Region (SNP) | VAF 32/124 reads (26%) | catalogued as COSV100730333; called by muse, mutect2, varscan2
- GRB14 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV55736934; called by muse, mutect2, varscan2
- GRIP1 | c.2320G>A p.D774N (on ENST00000359742 / NM_001379345.1; = p.D722N on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54019780; called by muse, mutect2, varscan2
- GTF3C1 | c.5588G>A p.R1863H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs370190480; called by muse, mutect2, varscan2
- GTF3C6 | c.464C>T p.S155L | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV57332714; called by muse, varscan2
- GTF3C6 | c.496G>A p.E166K | Missense Mutation (SNP) | VAF 33/94 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.026); catalogued as COSV57332722; called by muse, varscan2
- GYG1 | c.334G>A p.D112N | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56049231; called by muse, mutect2, varscan2
- H2AC12 | c.364G>A p.E122K | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.066); catalogued as COSV63616825; called by muse, mutect2, varscan2
- H2AC14 | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV60797443; called by muse, mutect2, varscan2
- H2AC15 | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV57585312; called by muse, mutect2, varscan2
- H2AW | c.228G>C p.K76N | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as COSV64209671; called by muse, mutect2, varscan2
- H3-3B | c.350G>A p.R117K | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.104); catalogued as COSV54665799, COSV54665867; called by muse, varscan2
- H3C10 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.904); catalogued as COSV60797298, COSV60799019; called by muse, mutect2, varscan2
- H3C7 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV55099645; called by muse, varscan2
- HACL1 | c.262C>G p.L88V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.609); catalogued as COSV58254044; called by muse, mutect2, varscan2
- HAO2 | c.83G>C p.G28A | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as COSV58038841, COSV58039242; called by muse, varscan2
- HAUS6 | c.1690G>C p.E564Q | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.28); catalogued as COSV65839756; called by muse, mutect2, varscan2
- HCFC2 | c.1170G>C p.L390F | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57558294; called by muse, mutect2, varscan2
- HCK | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV52941529; called by muse, mutect2, varscan2
- HDAC6 | c.1521C>G p.I507M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV61928252; called by muse, mutect2
- HES1 | c.412C>G p.R138G | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV51684314, COSV51684639; called by muse, mutect2, varscan2
- HK2 | c.1614C>A p.F538L | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV51873260, COSV51874276; called by muse, mutect2, varscan2
- HLA-A | c.601G>T p.E201* | Nonsense Mutation (SNP) | VAF 8/47 reads (17%) | catalogued as COSV65139114, COSV65141540; called by muse, mutect2, varscan2
- HLA-B | c.862G>T p.E288* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | catalogued as COSV69520871; called by muse, varscan2
- HLA-B | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 14/74 reads (19%) | catalogued as COSV69520875; called by muse, varscan2
- HLA-DMA | c.776C>G p.S259* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as COSV66385529; called by muse, mutect2, varscan2
- HLA-DQA1 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58238109; called by muse, mutect2, varscan2
- HMCN1 | c.8755C>T p.H2919Y | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.89); PolyPhen possibly damaging (0.462); catalogued as rs780752235, COSV54883630; called by muse, mutect2, varscan2
- HNRNPUL1 | c.516G>C p.K172N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV54561282; called by muse, mutect2, varscan2
- HSD17B13 | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as COSV56345737, COSV56345882; called by muse, mutect2, varscan2
- HSPBAP1 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV60241780; called by muse, mutect2, varscan2
- HSPG2 | c.10645G>T p.D3549Y | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65932959; called by muse, mutect2, varscan2
- HSPG2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65970366; called by muse, mutect2, varscan2
- HSPG2 | c.2984C>G p.S995* | Nonsense Mutation (SNP) | VAF 29/88 reads (33%) | catalogued as COSV65970368; called by muse, mutect2, varscan2
- HTRA3 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.148); catalogued as rs200701195, COSV100246228; called by muse, varscan2
- HYDIN | c.7847C>T p.S2616L | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59253487; called by mutect2, varscan2
- HYDIN | c.4274A>G p.D1425G | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV66831226; called by muse, mutect2, varscan2
- ICAM3 | c.566C>G p.S189* | Nonsense Mutation (SNP) | VAF 19/69 reads (28%) | catalogued as COSV50328798; called by muse, mutect2, varscan2
- IFIT1B | c.865C>T p.H289Y | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as COSV65663366; called by muse, mutect2, varscan2
- IFRD2 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57113105; called by muse, mutect2, varscan2
- IFT172 | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.246); catalogued as rs763372262, COSV53131817; called by muse, mutect2, varscan2
- IFT46 | c.224C>T p.S75F (on ENST00000264021 / NM_001168618.2; = p.S126F on NM_020153.3) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV50594026; called by muse, mutect2, varscan2
- IGSF10 | c.7502G>C p.R2501T | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV56374006, COSV56375996; called by muse, mutect2, varscan2
- IGSF10 | c.1145G>C p.S382T | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56783434; called by muse, mutect2, varscan2
- IKBKB | c.1008G>C p.L336F | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.483); catalogued as COSV60596548; called by muse, mutect2
- IL16 | c.3495C>G p.I1165M (on ENST00000302987 / NM_172217.5; = p.I464M on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100250765; called by muse, mutect2, varscan2
- IL17C | c.248C>T p.S83L | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV54918340; called by muse, mutect2, varscan2
- IL1A | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.356); catalogued as COSV54519270; called by muse, mutect2, varscan2
- IL1RAPL2 | c.564G>C p.W188C | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as COSV61149701; called by muse, mutect2, varscan2
- IL6ST | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.733); catalogued as COSV61140578; called by muse, mutect2, varscan2
- IMPDH2 | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.094); catalogued as COSV58244470; called by muse, mutect2, varscan2
- IMPG2 | c.414G>A p.M138I | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV51975926; called by muse, mutect2, varscan2
- INPP5D | c.1644G>C p.K548N (on ENST00000445964 / NM_001017915.3; = p.K547N on NM_005541.5) | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64036329; called by muse, mutect2, varscan2
- INSIG1 | c.108G>C p.E36D | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as COSV60920133; called by muse, mutect2, varscan2
- IQGAP1 | c.3724C>G p.L1242V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV51583304; called by muse, mutect2, varscan2
- IRGQ | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.14); catalogued as COSV60670428; called by muse, mutect2
- IRS1 | c.2626G>C p.E876Q | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.599); catalogued as COSV59334977; called by muse, mutect2, varscan2
- ITGA1 | c.3416G>A p.R1139K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.71); PolyPhen benign (0.001); catalogued as COSV50878939; called by muse, mutect2, varscan2
- ITGAL | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.01); catalogued as COSV63319969; called by muse, mutect2, varscan2
- ITGAL | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV63320752; called by muse, mutect2, varscan2
- ITGB4 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52323667; called by muse, mutect2, varscan2
- ITGB8 | c.714G>C p.E238D | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.475); catalogued as rs370739263; called by muse, mutect2, varscan2
- ITIH6 | c.2452C>T p.P818S | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV54487943; called by muse, mutect2, varscan2
- JMJD1C | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV67859893; called by muse, mutect2, varscan2
- JUP | c.1880C>T p.S627L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs781883243, COSV60277536; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNAB2 | c.563C>T p.S188L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV51236136; called by muse, mutect2, varscan2
- KCNJ12 | c.306C>G p.F102L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.432); catalogued as COSV100054128; called by muse, mutect2, varscan2
- KCNQ1 | c.1895G>A p.R632K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.62); PolyPhen benign (0.036); catalogued as COSV50103544, COSV50134539; called by muse, mutect2
- KCNU1 | c.3350C>T p.S1117L | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs773111998, COSV67754560; called by muse, mutect2, varscan2
- KCTD10 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57326435; called by muse, mutect2, varscan2
- KCTD20 | c.898G>T p.E300* | Nonsense Mutation (SNP) | VAF 17/71 reads (24%) | catalogued as COSV54802798; called by muse, mutect2, varscan2
- KDELR3 | c.202C>G p.L68V | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.11); catalogued as COSV53247113; called by muse, mutect2, varscan2
- KDM4B | c.3031G>C p.E1011Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.117); catalogued as COSV50213584; called by muse, mutect2, varscan2
- KDM5A | c.3283G>A p.E1095K | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.776); catalogued as rs1354074967, COSV66991517, COSV66992416; called by muse, varscan2
- KIAA0232 | c.426G>C p.Q142H | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100300953, COSV56924282; called by muse, mutect2, varscan2
- KIAA1614 | c.2846C>G p.S949* | Nonsense Mutation (SNP) | VAF 11/35 reads (31%) | catalogued as COSV62550649; called by muse, mutect2, varscan2
- KIF12 | c.679C>G p.L227V (on ENST00000640217; = p.L89V on NM_138424.1) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs35480554, COSV65116983; called by muse, mutect2, varscan2
- KIF13B | c.1201G>C p.E401Q | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV73054212; called by muse, mutect2, varscan2
- KIF14 | c.4765G>C p.D1589H | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.452); catalogued as COSV66260957; called by muse, mutect2, varscan2
- KIF19 | c.258G>C p.K86N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.643); catalogued as COSV63429187; called by muse, mutect2, varscan2
- KIF1C | c.2334G>C p.K778N | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV57903810; called by muse, mutect2, varscan2
- KIF27 | c.2305G>C p.E769Q | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.172); catalogued as COSV52826492; called by muse, mutect2, varscan2
- KIF2A | c.177C>G p.I59M | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as COSV66945141; called by muse, mutect2, varscan2
- KIF5B | c.2262G>C p.L754F | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.882); catalogued as COSV56652096; called by muse, mutect2, varscan2
- KIF5C | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68480569, COSV68482881; called by muse, mutect2, varscan2
- KLF6 | c.347C>G p.S116C | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as COSV51494251; called by muse, mutect2, varscan2
- KLHL14 | c.1288G>A p.G430S | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748172307, COSV63831716; called by muse, mutect2
- KLHL17 | c.562C>T p.Q188* | Nonsense Mutation (SNP) | VAF 16/59 reads (27%) | catalogued as COSV58531287; called by muse, mutect2, varscan2
- KLHL5 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs573552766, COSV54673004; called by muse, mutect2, varscan2
- KLHL8 | c.118G>C p.D40H | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.159); catalogued as COSV56747367; called by muse, mutect2
- KMT2C | c.7013C>T p.S2338L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.026); catalogued as COSV51424684; called by muse, mutect2, varscan2
- KMT2C | c.3923C>G p.S1308* | Nonsense Mutation (SNP) | VAF 24/98 reads (24%) | catalogued as COSV51424708; called by muse, mutect2, varscan2
- KMT2E | c.5233C>G p.Q1745E | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV57571500; called by muse, mutect2, varscan2
- KMT5A | c.211C>T p.Q71* | Nonsense Mutation (SNP) | VAF 25/84 reads (30%) | catalogued as COSV57862699; called by muse, mutect2, varscan2
- KRT10 | c.669G>C p.Q223H | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV54089119; called by muse, mutect2, varscan2
- KRT20 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as COSV51424410; called by muse, mutect2, varscan2
- KRT37 | c.1231G>A p.E411K | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as rs748701467, COSV56657370; called by muse, mutect2, varscan2
- KRT9 | c.33G>C p.L11F | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.01); catalogued as COSV55852273; called by muse, mutect2, varscan2
- KRTAP20-1 | c.134C>G p.S45C | Missense Mutation (SNP) | VAF 17/112 reads (15%) | PolyPhen benign (0.055); catalogued as COSV58168050; called by muse, mutect2, varscan2
- KRTAP5-3 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.068); catalogued as COSV68790638; called by muse, mutect2, varscan2
- KRTAP9-3 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.631); catalogued as COSV68616431; called by muse, mutect2, varscan2
- KSR1 | c.261G>C p.Q87H | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.263); catalogued as COSV52030204, COSV52037400; called by muse, mutect2, varscan2
- KTN1 | c.1612G>C p.D538H | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68022981; called by muse, varscan2
- L3MBTL3 | c.1078G>C p.E360Q | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.151); catalogued as COSV62385270; called by muse, mutect2, varscan2
- LAMA3 | c.8458C>G p.L2820V (on ENST00000313654 / NM_198129.4; = p.L1211V on NM_000227.6) | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52532598; called by muse, mutect2, varscan2
- LARP1 | c.1453C>T p.L485F (on ENST00000518297 / NM_033551.3; = p.L408F on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV60425862; called by muse, mutect2, varscan2
- LARP1 | c.2913C>G p.F971L (on ENST00000518297 / NM_033551.3; = p.F894L on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV60425874; called by muse, mutect2, varscan2
- LARP6 | c.255G>A p.W85* | Nonsense Mutation (SNP) | VAF 7/29 reads (24%) | catalogued as COSV54579514; called by muse, mutect2, varscan2
- LARS1 | c.2586C>G p.F862L (on ENST00000394434 / NM_020117.11; = p.F835L on NM_016460.3) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs749087544, COSV50973674; called by muse, mutect2, varscan2
- LATS1 | c.2045G>C p.R682T | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV53588650; called by muse, varscan2
- LDB2 | c.459G>C p.M153I | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs746746213, COSV58765788; called by muse, mutect2, varscan2
- LDHC | c.356C>T p.S119L | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV55003847; called by muse, mutect2, varscan2
- LEO1 | c.1505G>C p.R502T | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55175265; called by muse, mutect2, varscan2
- LGI3 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as rs778679674, COSV60443171, COSV60444265; called by muse, mutect2, varscan2
- LGR6 | c.2713C>T p.Q905* (on ENST00000367278 / NM_001017403.1; = p.Q853* on NM_021636.3) | Nonsense Mutation (SNP) | VAF 19/51 reads (37%) | catalogued as COSV55154375; called by muse, mutect2, varscan2
- LIMS1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 23/199 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV100185299, COSV57539833; called by muse, mutect2, varscan2
- LIPE | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV54922109; called by muse, mutect2, varscan2
- LMO3 | c.8C>G p.S3* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as COSV53781845; called by muse, mutect2, varscan2
- LRCH2 | c.2103C>G p.P701= | Splice Region (SNP) | VAF 31/117 reads (26%) | catalogued as COSV57748250; called by muse, mutect2, varscan2
- LRIF1 | c.62C>T p.S21L | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV63896890, COSV63897061; called by muse, mutect2, varscan2
- LRIG3 | c.278C>G p.S93C | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.628); catalogued as COSV57862213; called by muse, mutect2, varscan2
- LRRIQ1 | c.4451C>G p.S1484* | Nonsense Mutation (SNP) | VAF 20/98 reads (20%) | catalogued as COSV67828349, COSV67833270; called by muse, mutect2, varscan2
- LRRN2 | c.993C>G p.F331L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65783466; called by muse, mutect2, varscan2
- LRRTM3 | c.304G>C p.E102Q | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.832); catalogued as rs768106538, COSV63663601, COSV63669725; called by muse, mutect2, varscan2
- LSG1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.206); catalogued as COSV54569254; called by muse, varscan2
- LYPD6B | c.442C>G p.H148D (on ENST00000409029 / NM_001317004.1; = p.H172D on NM_177964.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.173); catalogued as rs759866478, COSV54518243, COSV54519476; called by muse, mutect2, varscan2
- MACF1 | c.10977G>C p.L3659F (on ENST00000372915; = p.L1592F on NM_012090.5) | Missense Mutation (SNP) | VAF 6/13 reads (46%) | catalogued as COSV57114590; called by muse, mutect2, varscan2
- MAGOHB | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs754343052, COSV57898206, COSV57899181; called by muse, mutect2, varscan2
- MAMDC4 | c.3487C>G p.L1163V (on ENST00000445819; = p.L1084V on NM_206920.3) | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV56375288; called by muse, mutect2, varscan2
- MAML2 | c.1385C>G p.S462* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV73263086; called by muse, mutect2, varscan2
- MAMLD1 | c.298C>G p.H100D | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV53373474; called by muse, mutect2, varscan2
- MAP3K5 | c.2430G>C p.L810F | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62888302; called by muse, mutect2, varscan2
- MAP7D2 | c.1028G>A p.R343K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV65526472; called by muse, mutect2, varscan2
- MAPK9 | c.877C>G p.Q293E | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.103); catalogued as COSV58120410; called by muse, mutect2, varscan2
- MAPKBP1 | c.1390G>C p.E464Q (on ENST00000456763 / NM_001128608.2; = p.E458Q on NM_014994.3) | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.432); catalogued as rs772940921, COSV52959707; called by muse, mutect2, varscan2
- MARF1 | c.5098C>T p.P1700S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.007); catalogued as COSV60021711; called by muse, mutect2, varscan2
- MARK3 | c.2110G>A p.D704N (on ENST00000429436 / NM_001128918.3; = p.D680N on NM_002376.6) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.836); catalogued as rs756154872, COSV53508821; called by muse, mutect2, varscan2
- MARS1 | c.12C>G p.F4L | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as rs761521550, COSV56253498; called by muse, varscan2
- MAST2 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs748930586, COSV63617349; called by muse, mutect2, varscan2
- MAST4 | c.1876G>A p.E626K (on ENST00000403625 / NM_001164664.2; = p.E437K on NM_015183.3) | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55120623; called by muse, mutect2, varscan2
- MAVS | c.545C>G p.S182C | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.826); catalogued as COSV63926634; called by muse, mutect2, varscan2
- MAVS | c.1438G>C p.E480Q | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.605); catalogued as COSV63926651; called by muse, mutect2, varscan2
- MAZ | c.1108-1G>A p.X370_splice | Splice Site (SNP) | VAF 7/22 reads (32%) | catalogued as COSV50714420; called by muse, mutect2, varscan2
- MBD6 | c.1592G>C p.G531A | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.115); catalogued as COSV63073785; called by muse, mutect2, varscan2
- MCF2L | c.15G>C p.W5C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.093); catalogued as COSV65092110; called by muse, mutect2, varscan2
- MCHR2 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.73); PolyPhen benign (0.012); catalogued as rs142259467, COSV56001077; called by muse, mutect2, varscan2
- MCMDC2 | c.1347G>C p.Q449H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV58034907; called by muse, mutect2, varscan2
- MDN1 | c.7239G>T p.E2413D | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV65519793; called by muse, mutect2, varscan2
- MECOM | c.2107G>A p.E703K (on ENST00000468789 / NM_001105078.4; = p.E891K on NM_004991.4) | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV52962197; called by muse, mutect2, varscan2
- MECOM | c.639C>G p.C213W (on ENST00000468789 / NM_001105078.4; = p.C401W on NM_004991.4) | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52962213; called by muse, mutect2, varscan2
- MED1 | c.3405G>C p.Q1135H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.496); catalogued as COSV56123589; called by muse, mutect2, varscan2
- MED17 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 49/135 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52600160; called by muse, mutect2, varscan2
- MED23 | c.2287G>A p.E763K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63431608; called by muse, mutect2, varscan2
- MED29 | c.285G>C p.L95F (on ENST00000615911; = p.L74F on NM_017592.4) | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV55393213, COSV99655936; called by muse, mutect2, varscan2
- MED29 | c.339-1G>C p.X113_splice (on ENST00000615911; = p.X92_splice on NM_017592.4) | Splice Site (SNP) | VAF 8/29 reads (28%) | catalogued as COSV55393220; called by muse, mutect2, varscan2
- MEI1 | c.2799G>A p.M933I | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as COSV55901963; called by muse, mutect2, varscan2
- MEIS1 | c.140C>G p.S47W | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.708); catalogued as COSV55485153; called by muse, mutect2, varscan2
- MIA3 | c.1456G>C p.E486Q | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV100719333; called by muse, mutect2
- MKI67 | c.4006C>G p.P1336A | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as COSV100896246, COSV64073601; called by muse, mutect2, varscan2
- MMP2 | c.1896C>G p.F632L | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.966); catalogued as COSV50894768, COSV50898381; called by muse, mutect2, varscan2
- MMP20 | c.899C>G p.S300* | Nonsense Mutation (SNP) | VAF 24/87 reads (28%) | catalogued as COSV52774821; called by muse, mutect2, varscan2
- MMP9 | c.871C>A p.P291T | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63433924; called by muse, varscan2
- MPDZ | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV59938138, COSV59943500; called by muse, mutect2, varscan2
- MRPS18B | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.417); catalogued as COSV52541153; called by muse, mutect2, varscan2
- MSN | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV64303690; called by muse, mutect2, varscan2
- MTHFR | c.16A>G p.R6G | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as CM013904, COSV56739004; called by muse, mutect2, varscan2
- MTMR1 | c.1298C>T p.S433F | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64892320; called by muse, mutect2, varscan2
- MTMR11 | c.583C>G p.L195V (on ENST00000439741 / NM_001145862.2; = p.L123V on NM_181873.3) | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV63805411; called by muse, mutect2, varscan2
- MTMR14 | c.1817C>T p.S606L (on ENST00000296003 / NM_001077525.3; = p.S494L on NM_022485.5) | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.115); catalogued as COSV56004166; called by muse, mutect2, varscan2
- MTREX | c.1618G>C p.D540H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV57924851; called by muse, mutect2, varscan2
- MTUS2 | c.3657G>C p.K1219N (on ENST00000612955 / NM_001366650.1; = p.K198N on NM_015233.6) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV66420712; called by muse, mutect2, varscan2
- MUC16 | c.2435C>T p.S812F | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as COSV67456434; called by muse, mutect2, varscan2
- MUC17 | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as rs563774308, COSV60284368; called by muse, mutect2, varscan2
- MUC17 | c.11431G>C p.E3811Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.621); catalogued as COSV60284373, COSV60284948; called by muse, mutect2, varscan2
- MUC4 | c.2848C>G p.P950A | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.55); catalogued as rs745661294, COSV62140843, COSV62159674; called by muse, mutect2, varscan2
- MUS81 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.407); catalogued as COSV57259620; called by muse, mutect2, varscan2
- MVB12B | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.731); catalogued as COSV63257846; called by muse, mutect2, varscan2
- MYBPC2 | c.1946C>T p.S649L | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.23); catalogued as rs775056269, COSV63094393; called by muse, mutect2, varscan2
- MYCBP2 | c.9790C>T p.R3264C (on ENST00000357337; = p.R3302C on NM_015057.5) | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs201714806, COSV62014295; called by muse, mutect2, varscan2
- MYH1 | c.2548G>C p.E850Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.175); catalogued as COSV56846051, COSV56857179; called by muse, mutect2, varscan2
- MYH13 | c.2869G>C p.D957H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52824090; called by muse, mutect2, varscan2
- MYH13 | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.367); catalogued as COSV52824105; called by muse, mutect2, varscan2
- MYH15 | c.3325G>C p.E1109Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV56307348; called by muse, mutect2, varscan2
- MYH2 | c.4177G>C p.E1393Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55434934; called by muse, mutect2, varscan2
- MYH4 | c.2716G>A p.E906K | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs966567437, COSV55115620; called by muse, mutect2, varscan2
- MYH8 | c.1898-1G>C p.X633_splice | Splice Site (SNP) | VAF 24/64 reads (38%) | catalogued as COSV67962632; called by muse, mutect2, varscan2
- MYO1E | c.3154C>T p.Q1052* | Nonsense Mutation (SNP) | VAF 7/37 reads (19%) | catalogued as COSV55684503; called by muse, mutect2, varscan2
- NAA38 | c.211G>T p.D71Y (on ENST00000575771 / NM_001320925.2; = p.D119Y on NM_032356.5) | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54679830; called by muse, mutect2, varscan2
- NAP1L1 | c.37G>C p.D13H | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs1317846793, COSV53873958; called by muse, mutect2, varscan2
- NAV3 | c.5995G>C p.E1999Q (on ENST00000397909 / NM_001024383.2; = p.E1977Q on NM_014903.6) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV57071604; called by muse, mutect2
- NBAS | c.5032C>G p.L1678V | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.77); catalogued as rs1341699816, COSV55712935; called by muse, mutect2, varscan2
- NBEA | c.8308C>G p.P2770A | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV59772071; called by muse, mutect2, varscan2
- NBPF1 | c.1810G>C p.E604Q | Missense Mutation (SNP) | VAF 10/139 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); catalogued as rs759155864, COSV55328321, COSV99844135; called by muse, mutect2
- NBPF9 | c.1513G>C p.D505H | Missense Mutation (SNP) | VAF 75/267 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.8); catalogued as COSV99913432; called by muse, mutect2, varscan2
- NCAPD2 | c.3456C>G p.F1152L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59698564; called by muse, mutect2, varscan2
- NCF4 | c.148G>C p.G50R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50620966; called by muse, mutect2, varscan2
- NCL | c.1495G>C p.E499Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV59545425; called by muse, mutect2, varscan2
- NCOA2 | c.4042C>T p.Q1348* | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as COSV51218804; called by muse, mutect2, varscan2
- NCOA5 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV51642476, COSV51643517; called by muse, mutect2, varscan2
- NCOR1 | c.3602G>A p.R1201K | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV51969157; called by muse, mutect2, varscan2
- NDC1 | c.1050C>G p.F350L | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV52334338; called by muse, mutect2, varscan2
- NDRG3 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.036); catalogued as COSV62421484; called by muse, mutect2, varscan2
- NDRG4 | c.159C>G p.F53L (on ENST00000570248 / NM_001378344.1; = p.F85L on NM_020465.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs760614649, COSV50747045, COSV50751086; called by muse, mutect2, varscan2
- NDST2 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.077); catalogued as COSV55213588; called by muse, mutect2, varscan2
- NDUFA11 | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV53135684; called by muse, mutect2, varscan2
- NFAT5 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.784); catalogued as rs1045442546, COSV63026261; called by muse, mutect2, varscan2
- NFATC3 | c.2141C>G p.S714* | Nonsense Mutation (SNP) | VAF 6/36 reads (17%) | catalogued as COSV60472396; called by muse, mutect2, varscan2
- NFKBIB | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.066); catalogued as rs751191975, COSV100548304; called by muse, mutect2, varscan2
- NFKBID | c.883G>A p.E295K (on ENST00000396901; = p.E447K on NM_032721.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as COSV100573202, COSV61728149; called by muse, mutect2, varscan2
- NHLRC1 | c.1141G>A p.D381N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61481293; called by muse, mutect2, varscan2
- NLN | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66765366; called by muse, mutect2, varscan2
- NLRP11 | c.2269C>T p.P757S | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.254); catalogued as COSV64086520; called by muse, mutect2, varscan2
- NLRP2 | c.2185C>G p.H729D | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.044); catalogued as COSV99671957; called by muse, mutect2, varscan2
- NLRP4 | c.1308G>T p.K436N | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.703); catalogued as COSV100015722, COSV56723869; called by muse, mutect2, varscan2
- NLRP6 | c.1783G>C p.E595Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.149); catalogued as COSV56458845; called by muse, mutect2, varscan2
- NLRP6 | c.1927G>A p.E643K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); catalogued as COSV56458858; called by muse, mutect2, varscan2
- NLRP9 | c.2334G>C p.L778F | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV60461539; called by muse, mutect2, varscan2
- NMNAT3 | c.595G>C p.E199Q (on ENST00000296202 / NM_001320512.1; = p.E162Q on NM_178177.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56155641; called by muse, mutect2, varscan2
- NOA1 | c.2085G>C p.K695N | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); catalogued as COSV51736392; called by muse, mutect2, varscan2
- NOM1 | c.1815G>C p.Q605H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV51979440; called by muse, mutect2, varscan2
- NOM1 | c.2157G>C p.R719S | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51979452; called by muse, mutect2, varscan2
- NOS3 | c.3091G>A p.D1031N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.157); catalogued as COSV52487791; called by muse, varscan2
- NOXRED1 | c.839C>G p.S280C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV53627815; called by muse, mutect2, varscan2
- NPAP1 | c.1042C>G p.R348G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.979); catalogued as COSV61503908, COSV61505760; called by muse, mutect2
- NPM1 | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.458); catalogued as COSV51552524; called by muse, mutect2, varscan2
- NPR1 | c.1747G>C p.E583Q | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as COSV64117432; called by muse, mutect2, varscan2
- NPTX1 | c.1033C>T p.H345Y | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60774631; called by muse, mutect2, varscan2
- NRAP | c.4156C>G p.H1386D (on ENST00000359988 / NM_001322945.2; = p.H1351D on NM_006175.4) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100748297, COSV63488177; called by muse, mutect2, varscan2
- NRDC | c.1879-1G>A p.X627_splice | Splice Site (SNP) | VAF 15/63 reads (24%) | catalogued as COSV61403289; called by muse, mutect2, varscan2
- NRP1 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55163188; called by muse, mutect2, varscan2
- NRXN1 | c.2452G>T p.G818* | Nonsense Mutation (SNP) | VAF 14/39 reads (36%) | catalogued as COSV58444148; called by muse, mutect2, varscan2
- NSD3 | c.1926G>C p.M642I | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.006); catalogued as COSV100388513, COSV57617856; called by muse, mutect2, varscan2
- NSG1 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.663); catalogued as COSV67574794; called by muse, mutect2, varscan2
- NSMCE4A | c.989-1G>C p.X330_splice | Splice Site (SNP) | VAF 18/61 reads (30%) | catalogued as COSV64632687; called by muse, mutect2, varscan2
- NSRP1 | c.412G>C p.D138H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.601); catalogued as COSV55933503; called by muse, mutect2, varscan2
- NUAK2 | c.1289G>C p.S430T | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV65681136; called by muse, mutect2, varscan2
- NUDT10 | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 24/102 reads (24%) | catalogued as COSV62854030; called by muse, mutect2, varscan2
- NUP62 | c.1042G>A p.E348K | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.85); catalogued as COSV100351989, COSV61311455; called by muse, mutect2, varscan2
- NWD1 | c.2028G>C p.K676N | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV60340287; called by muse, mutect2, varscan2
- NYAP1 | c.434C>G p.S145* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as COSV55718110; called by muse, mutect2, varscan2
- NYNRIN | c.5488G>C p.D1830H | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV66841777; called by muse, mutect2, varscan2
- OBSL1 | c.2022G>C p.Q674H | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as COSV54716490, COSV54725299; called by muse, mutect2, varscan2
- ODF3 | c.592C>G p.P198A | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57293386; called by muse, mutect2, varscan2
- OGDH | c.1917G>C p.L639F | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV56047498; called by muse, mutect2, varscan2
- OLFM3 | c.589G>C p.E197Q (on ENST00000338858 / NM_001288821.1; = p.E177Q on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.174); catalogued as COSV58797385; called by muse, mutect2, varscan2
- OMA1 | c.1381G>A p.E461K | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV62254864; called by muse, mutect2, varscan2
- OMG | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.001); catalogued as COSV55987881; called by muse, mutect2, varscan2
- OR10A7 | c.807G>C p.E269D | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as COSV58278071; called by muse, mutect2, varscan2
- OR10G4 | c.535G>A p.D179N | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57977205; called by muse, mutect2, varscan2
- OR4C12 | c.664T>C p.S222P | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); catalogued as COSV58859724; called by muse, mutect2, varscan2
- OR51M1 | c.483C>G p.I161M | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as COSV60784193; called by muse, mutect2, varscan2
- OR52E2 | c.881G>C p.G294A | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as COSV58612229, COSV58612275; called by muse, mutect2, varscan2
- OR56B1 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.955); catalogued as COSV57722697, COSV57723201; called by muse, mutect2, varscan2
- OR56B4 | c.409C>T p.Q137* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as COSV57203692; called by muse, mutect2, varscan2
- OR5D14 | c.394C>G p.L132V | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs949576164, COSV59455912; called by muse, mutect2, varscan2
- OR6C74 | c.688C>G p.Q230E | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.092); catalogued as COSV59606057; called by muse, mutect2
- ORC4 | c.607G>C p.E203Q | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51572755, COSV51577173; called by muse, mutect2, varscan2
- OSBP | c.2163G>C p.Q721H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55661694, COSV55664039; called by muse, mutect2, varscan2
- OSBPL3 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV57654880; called by muse, mutect2, varscan2
- OSBPL9 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV61868227; called by muse, mutect2, varscan2
- OTUD3 | c.277C>G p.L93V | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.009); catalogued as COSV64295630; called by muse, mutect2, varscan2
- OTUD3 | c.1080G>C p.E360D | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as COSV64295639; called by muse, mutect2, varscan2
- P3H1 | c.1531G>A p.E511K | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as COSV52532601; called by muse, varscan2
- PADI3 | c.907C>G p.L303V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.191); catalogued as COSV64934324; called by muse, varscan2
- PAK4 | c.737C>T p.S246F | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as COSV58944546; called by muse, mutect2, varscan2
- PALMD | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.853); catalogued as COSV54163740; called by muse, mutect2, varscan2
- PAM | c.1175C>T p.S392L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV57211603; called by muse, mutect2, varscan2
- PAOX | c.319C>T p.H107Y | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.982); catalogued as COSV53371769; called by muse, mutect2, varscan2
- PAPPA2 | c.4741G>A p.E1581K | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV62794199; called by muse, mutect2
- PARP1 | c.2038G>C p.E680Q | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as rs1479237968, COSV64689807, COSV64690655; called by muse, mutect2, varscan2
- PATZ1 | c.460G>T p.E154* | Nonsense Mutation (SNP) | VAF 7/26 reads (27%) | catalogued as COSV53229071; called by muse, mutect2, varscan2
- PCDH1 | c.2742G>C p.K914N | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as COSV54612737; called by muse, mutect2, varscan2
- PCDHA3 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | catalogued as COSV65366052; called by muse, mutect2, varscan2
- PCDHA9 | c.1508C>T p.S503L | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as rs782017581, COSV65324990; called by muse, mutect2, varscan2
- PCDHB12 | c.877G>C p.E293Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.05); catalogued as COSV53394838, COSV53400877; called by muse, mutect2, varscan2
- PCDHGB3 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV53922986; called by muse, mutect2, varscan2
- PCED1B | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV71395011, COSV71395060; called by muse, mutect2, varscan2
- PCID2 | c.750G>A p.M250I | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV55813336; called by muse, mutect2, varscan2
- PCM1 | c.4408G>C p.D1470H | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59586033; called by muse, mutect2, varscan2
- PCNX1 | c.5720C>G p.S1907C | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.903); catalogued as COSV53092107; called by muse, mutect2, varscan2
- PCOLCE | c.844C>T p.Q282* | Nonsense Mutation (SNP) | VAF 26/109 reads (24%) | catalogued as COSV56159829; called by muse, mutect2, varscan2
- PCSK5 | c.471G>C p.K157N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as COSV65086747; called by muse, mutect2, varscan2
- PDE1A | c.865G>C p.E289Q | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59519357; called by muse, mutect2, varscan2
- PDK1 | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.109); catalogued as COSV56374827; called by muse, mutect2, varscan2
- PDLIM5 | c.103G>C p.D35H | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV58746496; called by muse, varscan2
- PDZD2 | c.3190G>T p.E1064* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV56854962; called by muse, mutect2, varscan2
- PDZD3 | c.559C>T p.R187W (on ENST00000531114; = p.R121W on NM_024791.4) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1376724370, COSV52702913; called by muse, mutect2, varscan2
- PDZD8 | c.2374C>G p.H792D | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.024); catalogued as COSV53689468; called by muse, mutect2, varscan2
- PEG3 | c.3821G>C p.R1274T | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as COSV55626549, COSV55629647, COSV99689157; called by muse, mutect2, varscan2
- PEX14 | c.901G>C p.G301R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV63060709; called by muse, mutect2, varscan2
- PHF13 | c.769C>T p.H257Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50010798; called by muse, mutect2, varscan2
- PHF3 | c.2952G>C p.L984F | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV50315628; called by muse, mutect2, varscan2
- PHLDB2 | c.877C>T p.H293Y | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.062); catalogued as COSV67309812; called by muse, mutect2
- PIK3C2B | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.027); catalogued as rs144719096; called by muse, mutect2, varscan2
- PIK3R1 | c.1243C>T p.Q415* (on ENST00000521381 / NM_181523.3; = p.Q145* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 17/73 reads (23%) | catalogued as COSV57127794, COSV57128291; called by muse, mutect2, varscan2
- PIK3R1 | c.1394G>C p.R465T (on ENST00000521381 / NM_181523.3; = p.R195T on NM_181504.4) | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.151); catalogued as COSV57127827; called by muse, mutect2, varscan2
- PIK3R1 | c.1721G>T p.R574I (on ENST00000521381 / NM_181523.3; = p.R304I on NM_181504.4) | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV57125227, COSV57128628, COSV99144283; called by muse, varscan2
- PIP5K1C | c.1162G>A p.E388K | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as COSV58951243; called by muse, mutect2, varscan2
- PIWIL3 | c.7G>C p.G3R | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59994492, COSV59998462; called by muse, mutect2, varscan2
- PIWIL4 | c.538C>G p.Q180E | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54408707; called by muse, mutect2, varscan2
- PKD1L1 | c.4498C>G p.P1500A | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.23); catalogued as COSV56961662; called by muse, mutect2, varscan2
- PKHD1L1 | c.828C>A p.F276L | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.048); catalogued as COSV65740204, COSV65740467; called by muse, mutect2, varscan2
- PKHD1L1 | c.4682C>G p.S1561* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV65740472; called by muse, mutect2, varscan2
- PKM | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 22/79 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV58787523; called by muse, mutect2, varscan2
- PKP3 | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.058); catalogued as COSV100520939, COSV58986621; called by muse, mutect2, varscan2
- PLAAT5 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV57136668; called by muse, mutect2, varscan2
- PLCB1 | c.142C>G p.Q48E | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV62044857; called by muse, mutect2, varscan2
- PLCD3 | c.1569G>T p.Q523H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as rs768504307, COSV59559281; called by muse, mutect2, varscan2
- PLCD4 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV68842349; called by muse, mutect2, varscan2
- PLCG1 | c.1458C>G p.I486M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV54816979; called by muse, mutect2, varscan2
- PLEKHA5 | c.2015C>T p.S672L | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.904); catalogued as COSV54697454; called by muse, mutect2, varscan2
- PLEKHG1 | c.703C>G p.L235V | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV62046380; called by muse, mutect2, varscan2
- PLEKHG4 | c.662C>G p.S221C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as COSV64612233; called by muse, mutect2, varscan2
- PLP2 | c.406C>T p.R136W | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs782265454, COSV66239332; called by muse, mutect2, varscan2
- PLS3 | c.535G>C p.D179H | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV56777385; called by muse, mutect2, varscan2
- PLSCR4 | c.877G>C p.D293H | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as COSV100724296; called by muse, mutect2
- PLXDC1 | c.98C>T p.S33F | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV59550249; called by muse, mutect2, varscan2
- PLXNA2 | c.3436G>A p.E1146K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV65439248; called by muse, mutect2, varscan2
- PLXNC1 | c.4441G>C p.E1481Q | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51572935, COSV99313734; called by muse, mutect2, varscan2
- PLXND1 | c.3901G>A p.E1301K | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1285397379, COSV60711175; called by muse, mutect2, varscan2
- PMPCA | c.901G>C p.E301Q | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV65509321; called by muse, mutect2, varscan2
- PNLIPRP2 | c.869C>G p.S290* | Nonsense Mutation (SNP) | VAF 23/103 reads (22%) | catalogued as COSV53943074; called by muse, mutect2, varscan2
- PNRC1 | c.271C>T p.R91W | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs747140961, COSV60139423; called by muse, mutect2
- POLK | c.727G>T p.E243* | Nonsense Mutation (SNP) | VAF 21/75 reads (28%) | catalogued as COSV54033701; called by muse, mutect2, varscan2
- POLR1A | c.3535G>C p.E1179Q | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.744); catalogued as COSV55691310; called by muse, mutect2, varscan2
- POLR2B | c.2503G>A p.E835K | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.43); PolyPhen benign (0.102); catalogued as COSV58899584; called by muse, mutect2, varscan2
- POLR2F | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs759220077, COSV68091369; called by muse, mutect2, varscan2
- PPARGC1B | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV58528061; called by muse, mutect2, varscan2
- PPEF2 | c.1649+2C>T p.X550_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as COSV54420254; called by muse, mutect2, varscan2
- PPFIA1 | c.3367G>A p.D1123N | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.194); catalogued as COSV54133139; called by muse, mutect2, varscan2
- PPFIA3 | c.1207G>C p.E403Q | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV61950701; called by muse, mutect2, varscan2
- PPIB | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 13/60 reads (22%) | catalogued as COSV55519805; called by muse, mutect2, varscan2
- PPIP5K2 | c.2893C>T p.P965S | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0.045); catalogued as COSV58604448; called by muse, mutect2, varscan2
- PPM1G | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.362); catalogued as COSV59769027; called by muse, mutect2, varscan2
- PPP1R10 | c.675G>C p.K225N | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV64738821; called by muse, mutect2, varscan2
- PPP1R16B | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55375921; called by muse, mutect2, varscan2
- PPP1R1A | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV54491258, COSV99226303; called by muse, mutect2, varscan2
- PPP1R21 | c.1534C>G p.L512V | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs1171127722, COSV54283543; called by muse, mutect2, varscan2
- PPP1R8 | c.138G>C p.K46N | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV52579734; called by muse, mutect2, varscan2
- PPP1R9B | c.1552G>C p.D518H | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV57541022; called by muse, mutect2, varscan2
- PPP2R3A | c.3165C>G p.F1055L | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.749); catalogued as rs775142377, COSV53861633, COSV53870811; called by muse, mutect2, varscan2
- PPP4R1 | c.1791G>C p.L597F (on ENST00000400556 / NM_001042388.3; = p.L580F on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.379); catalogued as COSV53281189; called by muse, mutect2, varscan2
- PPP6R2 | c.232C>G p.P78A | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.23); catalogued as COSV53291696; called by muse, mutect2, varscan2
- PRAMEF20 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 41/140 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.014); catalogued as rs779646091, COSV57080721; called by muse, mutect2, varscan2
- PREPL | c.1697G>A p.G566E | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751045968, COSV53215944; called by muse, mutect2, varscan2
- PREX1 | c.1834C>G p.R612G | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.203); catalogued as COSV64250064, COSV64254867; called by muse, mutect2, varscan2
- PRG4 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs113383997, COSV66623444; called by muse, mutect2, varscan2
- PRKCB | c.1230C>G p.F410L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV57773145; called by muse, mutect2, varscan2
- PRKCI | c.372C>G p.I124M | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.09); catalogued as COSV55517643; called by muse, mutect2, varscan2
- PRKDC | c.8897C>G p.S2966C | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV58048145; called by muse, varscan2
- PRPF4 | c.388G>C p.E130Q (on ENST00000374198 / NM_001322267.2; = p.E131Q on NM_004697.5) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.903); catalogued as COSV65252470; called by muse, mutect2, varscan2
- PRPF4 | c.806G>A p.R269Q (on ENST00000374198 / NM_001322267.2; = p.R270Q on NM_004697.5) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.462); catalogued as rs975631250, COSV65252475; called by muse, mutect2, varscan2
- PRPF4B | c.2734-1G>A p.X912_splice | Splice Site (SNP) | VAF 24/79 reads (30%) | catalogued as COSV61783784; called by muse, mutect2, varscan2
- PRR12 | c.1939C>G p.Q647E (on ENST00000615927; = p.Q1468E on NM_020719.3) | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.97); PolyPhen benign (0.038); catalogued as COSV69817152; called by muse, mutect2
843 further variants in this file (392 protein-altering or splice-affecting, 418 silent, 33 other) are not listed here.
